Somatic mutation profile of tumor specimen TCGA-FC-A8O0-01A (aliquot TCGA-FC-A8O0-01A-41D-A377-08) from TCGA case TCGA-FC-A8O0, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 68.8 years (25,115 days).
Specimen TCGA-FC-A8O0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54796f0e-76bb-4f5d-923a-a935735f690b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FC-A8O0-10A (Blood Derived Normal), aliquot TCGA-FC-A8O0-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ed5bc78-eb26-4e5a-8910-400d6a46ead5

The open-access MAF lists 15 somatic variants for this specimen: 14 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 11, Nonsense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AR | c.1789G>A p.A597T | Missense Mutation (SNP) | VAF 27/35 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs137852569, CM920071, COSV65954647; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABHD16A | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 16/41 reads (39%) | catalogued as COSV65452133; called by muse, mutect2, varscan2
- ADAM29 | c.2200C>A p.P734T | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.18); catalogued as rs138923714; called by muse, varscan2
- ANGPT2 | c.1337G>A p.W446* | Nonsense Mutation (SNP) | VAF 11/114 reads (10%) | catalogued as COSV100291088; called by muse, mutect2
- CEP120 | c.2743C>G p.Q915E | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100071346; called by muse, mutect2, varscan2
- DBX2 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs368330243; called by muse, mutect2
- DYM | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as COSV99493765; called by muse, mutect2, varscan2
- ENPP5 | c.1045C>T p.H349Y | Missense Mutation (SNP) | VAF 90/281 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as rs1390622885, COSV100040537; called by muse, mutect2, varscan2
- FAM170A | c.887C>A p.A296E | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as rs760764849, COSV100089208; called by muse, mutect2, varscan2
- HNRNPH1 | c.1166G>A p.G389D | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.114); catalogued as rs764732453, COSV100270833; called by muse, mutect2, varscan2
- ITIH2 | c.2000C>T p.P667L | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.782); catalogued as rs1179672436, COSV64432663; called by muse, mutect2, varscan2
- PARP11 | c.626A>T p.E209V | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.199); catalogued as COSV99959175; called by muse, mutect2, varscan2
- TRPS1 | c.106G>T p.E36* (on ENST00000220888 / NM_001330599.2; = p.E49* on NM_014112.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 15/66 reads (23%) | catalogued as COSV55227703, COSV55239728; called by muse, mutect2, varscan2
- VWA3B | c.2039T>C p.L680S | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1157320652, COSV101346113; called by muse, mutect2
- SLC22A9 | c.1489C>T p.L497= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV99655258; called by muse, mutect2, varscan2
